CCDI case PBCTTA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/bd7da7dd-70c5-48bd-a462-fba8fbf78adc

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 14.2 years (5,185 days).

Biospecimens (3 samples)
- Sample 0DZ6FH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DZ6H4, 0E061N (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
